Gene-level copy-number profile of tumor specimen TCGA-24-1435-01A from TCGA case TCGA-24-1435, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.8 years (21,107 days).
Specimen TCGA-24-1435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b3ea5fa8-61c8-462e-b013-0e4d44fec679.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1435-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a310437-0a6a-497b-b195-298a13125acb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 75; copy number 2: 14,782; copy number 3: 6,626; copy number 4: 28,781; copy number 5: 3,525; copy number 6: 3,604; copy number 7: 831; copy number 8: 981; copy number 9: 198; copy number 10: 400; copy number 12: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1435-01A-01D-0472-01): tumor purity 0.71, ploidy 3.76, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:27,756,766–27,800,529, 1 gene (within-gene range 0–2): NOS2.
- chr22:49,372,924–49,377,119, 1 gene: AC207130.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 612 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:6,901,022–25,701,783, 281 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:94,895,767–95,116,455, 1 gene, copy number 10 (within-gene range 6–10): NDUFAF6.
- chr8:94,974,573–110,105,964, 261 genes, copy number 9–10 (broad region; genes not listed).
- chr8:143,304,384–144,326,910, 69 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 74. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
